Somatic mutation profile of tumor specimen TCGA-CI-6621-01A (aliquot TCGA-CI-6621-01A-11D-1826-10) from TCGA case TCGA-CI-6621, project TCGA-READ (Rectum Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectum, NOS; AJCC pathologic stage: Stage IIIB; Age at diagnosis: 63.6 years (23,240 days).
Specimen TCGA-CI-6621-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2bc0284b-619d-455e-8bd1-177c789d02b3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CI-6621-10A (Blood Derived Normal), aliquot TCGA-CI-6621-10A-01D-1826-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5d8523c0-c904-40a3-a12c-3acfa39f7dc0

The open-access MAF lists 113 somatic variants for this specimen: 83 protein-altering or splice-affecting, 30 silent.
By variant classification: Missense Mutation 70, Silent 30, Nonsense Mutation 7, Frame Shift Ins 2, Splice Site 2, Frame Shift Del 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.4057G>T p.E1353* | Nonsense Mutation (SNP) | VAF 30/49 reads (61%) | hotspot (GDC flag); catalogued as rs1114167568, CD972008, CM130060, COSV57321750, COSV57332693; ClinVar: pathogenic; called by muse, mutect2, varscan2
- FSHB | c.343C>T p.R115* | Nonsense Mutation (SNP) | VAF 10/30 reads (33%) | catalogued as rs374623109, COSV54221612; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.817C>T p.R273C | Missense Mutation (SNP) | VAF 14/27 reads (52%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913343, CM010471, CM010473, CM951233, COSV52662066, COSV52670856, COSV52707054, COSV53164203; ClinVar: not provided / uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ACP7 | c.1058G>A p.R353Q | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs1006409955, COSV100488543; called by muse, mutect2
- ACVR2B | c.691C>T p.R231W | Missense Mutation (SNP) | VAF 20/83 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.036); catalogued as rs970606066, COSV61702775; called by muse, mutect2, varscan2
- ANO4 | c.397G>T p.E133* (on ENST00000392977 / NM_001286615.2; = p.E98* on NM_178826.4) | Nonsense Mutation (SNP) | VAF 12/75 reads (16%) | catalogued as COSV100151725; called by muse, mutect2, varscan2
- ASTN1 | c.3394C>T p.R1132W | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs373152514, COSV62494292; called by muse, mutect2, varscan2
- AXIN1 | c.61C>T p.P21S | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51987576, COSV51994894; called by muse, mutect2, varscan2
- BEX1 | c.13G>T p.E5* | Nonsense Mutation (SNP) | VAF 11/87 reads (13%) | catalogued as COSV65580901; called by muse, mutect2, varscan2
- C3orf20 | c.954G>T p.M318I | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99514225; called by muse, mutect2, varscan2
- CACNA1E | c.4264A>C p.I1422L | Missense Mutation (SNP) | VAF 36/309 reads (12%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.759); catalogued as COSV62438510; called by muse, mutect2, varscan2
- CLRN1 | c.488A>T p.H163L (on ENST00000327047 / NM_174878.3; = p.H87L on NM_052995.2) | Missense Mutation (SNP) | VAF 36/125 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.207); catalogued as COSV99902546; called by muse, mutect2, varscan2
- CLSTN2 | c.1574G>A p.R525H | Missense Mutation (SNP) | VAF 19/40 reads (48%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs202013971, COSV71725808; called by muse, mutect2, varscan2
- CRAT | c.1140G>T p.K380N | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.822); catalogued as COSV58879587; called by muse, mutect2, varscan2
- CYP1A1 | c.1309G>A p.G437S | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.505); catalogued as COSV101122336; called by muse, varscan2
- DAAM2 | c.1726G>A p.G576S | Missense Mutation (SNP) | VAF 15/85 reads (18%) | SIFT tolerated (0.91); PolyPhen benign (0); catalogued as rs746541722, COSV51315319; called by muse, mutect2, varscan2
- DAPK3 | c.463C>A p.P155T | Missense Mutation (SNP) | VAF 9/87 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.247); catalogued as rs1445557672, COSV56665544; called by muse, mutect2, varscan2
- DMRTC2 | c.136C>T p.R46C | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54185661; called by muse, mutect2, varscan2
- DNAH5 | c.8407G>A p.G2803R | Missense Mutation (SNP) | VAF 20/78 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54242536; called by muse, mutect2, varscan2
- DYNC2H1 | c.1052G>A p.S351N | Missense Mutation (SNP) | VAF 36/123 reads (29%) | SIFT tolerated (0.35); PolyPhen benign (0.026); catalogued as COSV62109738; called by muse, mutect2, varscan2
- EPG5 | c.4063C>T p.R1355C | Missense Mutation (SNP) | VAF 14/27 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56357441; called by muse, mutect2, varscan2
- ESR1 | c.29C>G p.S10C | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.847); catalogued as COSV52804472; called by muse, mutect2
- EVA1A | c.197G>A p.R66H | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as COSV52060166; called by muse, mutect2, varscan2
- EVC | c.2032C>T p.R678C | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs767480367, COSV53830092; called by muse, mutect2, varscan2
- FOXN3 | c.161C>T p.A54V | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT tolerated (0.23); PolyPhen benign (0.075); catalogued as rs147377124; called by muse, mutect2, varscan2
- FRMPD1 | c.3542C>G p.P1181R | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); catalogued as COSV100899585; called by mutect2, varscan2
- FUT3 | c.178C>T p.R60C | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.54); catalogued as rs370374203; called by muse, mutect2, varscan2
- GPT2 | c.579G>T p.T193= | Splice Region (SNP) | VAF 8/22 reads (36%) | catalogued as COSV60840659; called by muse, mutect2, varscan2
- HCFC1 | c.4691C>T p.S1564F | Missense Mutation (SNP) | VAF 18/29 reads (62%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.367); catalogued as COSV60078833; called by muse, mutect2, varscan2
- IMPA2 | c.763G>A p.D255N | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.445); catalogued as rs747684756, COSV52319208; called by muse, mutect2, varscan2
- JAKMIP2 | c.1759C>T p.R587* | Nonsense Mutation (SNP) | VAF 18/97 reads (19%) | catalogued as COSV54617773; called by muse, varscan2
- KCTD21 | c.764G>A p.R255Q | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.994); catalogued as rs372134817; called by muse, mutect2, varscan2
- LMNA | c.692A>G p.N231S | Missense Mutation (SNP) | VAF 35/84 reads (42%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs760388350, COSV61543438; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MAML2 | c.2783G>T p.G928V | Missense Mutation (SNP) | VAF 79/194 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.023); catalogued as rs755203102, COSV73265085; called by muse, mutect2, varscan2
- MTNR1B | c.787T>A p.C263S | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV57069574; called by muse, mutect2, varscan2
- NCAM1 | c.1790T>A p.I597N (on ENST00000316851 / NM_181351.5; = p.I587N on NM_000615.7) | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated (0.3); PolyPhen benign (0.163); catalogued as COSV57527305; called by muse, mutect2, varscan2
- NVL | c.290C>G p.T97S | Missense Mutation (SNP) | VAF 25/73 reads (34%) | SIFT tolerated (0.87); PolyPhen benign (0); catalogued as COSV55877128; called by muse, mutect2, varscan2
- NXPH1 | c.377C>T p.S126F | Missense Mutation (SNP) | VAF 11/88 reads (13%) | SIFT tolerated (0.31); PolyPhen benign (0.405); catalogued as COSV68320499; called by muse, mutect2, varscan2
- OR1G1 | c.89C>A p.S30Y | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.013); catalogued as COSV100187567; called by mutect2, varscan2
- OTUD4 | c.1277G>C p.R426T (on ENST00000447906 / NM_001366057.1; = p.R361T on NM_001102653.1) | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.978); catalogued as COSV101486016, COSV71382250; called by muse, mutect2
- P2RY10 | c.810G>T p.K270N | Missense Mutation (SNP) | VAF 24/38 reads (63%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.955); catalogued as COSV50685435; called by muse, mutect2, varscan2
- P2RY10 | c.811G>T p.E271* | Nonsense Mutation (SNP) | VAF 24/38 reads (63%) | catalogued as COSV50681240, COSV50688257; called by muse, mutect2, varscan2
- PAPOLG | c.1465A>G p.K489E | Missense Mutation (SNP) | VAF 40/141 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.61); catalogued as COSV99474867; called by muse, mutect2, varscan2
- PHF20 | c.898C>T p.R300C | Missense Mutation (SNP) | VAF 37/105 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs762848107, COSV59187502; called by muse, mutect2, varscan2
- PLCD4 | c.995G>A p.R332H | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs561847468, COSV68843612; called by muse, mutect2, varscan2
- PLCG1 | c.2147G>A p.R716H | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1194857720, COSV54825353; called by muse, mutect2, varscan2
- POF1B | c.1070T>G p.M357R | Missense Mutation (SNP) | VAF 13/104 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV53142005; called by muse, mutect2, varscan2
- POSTN | c.1791+2T>G p.X597_splice | Splice Site (SNP) | VAF 10/93 reads (11%) | catalogued as COSV65715256; called by muse, mutect2, varscan2
- POTEM | c.191G>A p.W64* | Nonsense Mutation (SNP) | VAF 34/324 reads (10%) | catalogued as COSV69154672, COSV69156525; called by muse, varscan2
- PREX2 | c.3851C>T p.A1284V | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.022); catalogued as rs375506738; called by muse, mutect2, varscan2
- PYROXD1 | c.11C>G p.A4G | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.001); catalogued as COSV53712417; called by muse, mutect2, varscan2
- RFC5 | c.568G>A p.V190M | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.042); catalogued as rs760544254, COSV57479146; called by muse, mutect2, varscan2
- RNF180 | c.314G>T p.C105F | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV99684807; called by muse, mutect2, varscan2
- RP1 | c.2216A>G p.E739G | Missense Mutation (SNP) | VAF 37/141 reads (26%) | SIFT tolerated (0.25); PolyPhen benign (0.343); catalogued as COSV55129188; called by muse, mutect2, varscan2
- RPS6KC1 | c.1069A>T p.T357S | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.971); catalogued as COSV65303416; called by muse, mutect2, varscan2
- RSPH4A | c.1061G>A p.R354H | Missense Mutation (SNP) | VAF 29/86 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.229); catalogued as rs367712020; called by muse, mutect2, varscan2
- SACS | c.4415C>A p.P1472H | Missense Mutation (SNP) | VAF 21/75 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as COSV66548204; called by muse, mutect2, varscan2
- SASS6 | c.1247C>G p.A416G | Missense Mutation (SNP) | VAF 14/142 reads (10%) | SIFT tolerated (0.72); PolyPhen benign (0.062); catalogued as COSV54930920; called by muse, mutect2
- SFMBT2 | c.1306C>T p.R436W | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs201914057, COSV62818382; called by muse, mutect2
- SLC2A3 | c.1267G>A p.A423T | Missense Mutation (SNP) | VAF 42/123 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.889); catalogued as rs201737691, COSV50002302, COSV50003055; called by muse, mutect2, varscan2
- SLC8A2 | c.395C>T p.T132M | Missense Mutation (SNP) | VAF 21/67 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52643626; called by muse, mutect2, varscan2
- SLC8A3 | c.1661G>A p.R554Q | Missense Mutation (SNP) | VAF 21/64 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as rs982655652, COSV63521042, COSV63523482; called by muse, mutect2, varscan2
- SMARCA1 | c.608A>G p.N203S | Missense Mutation (SNP) | VAF 69/108 reads (64%) | SIFT tolerated (0.65); PolyPhen possibly damaging (0.51); catalogued as rs753408575, COSV64411769; called by muse, mutect2, varscan2
- SP5 | c.910G>A p.G304S | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.059); catalogued as rs779921916, COSV100935313; called by mutect2, varscan2
- SPATA19 | c.155G>A p.R52Q | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as rs371989839; called by muse, mutect2, varscan2
- ST6GALNAC1 | c.731C>T p.T244M | Missense Mutation (SNP) | VAF 25/102 reads (25%) | PolyPhen benign (0.025); catalogued as rs754834765, COSV99336503; called by muse, mutect2, varscan2
- STS | c.382+1G>C p.X128_splice | Splice Site (SNP) | VAF 5/20 reads (25%) | catalogued as COSV99481405; called by muse, mutect2
- SUPT20HL1 | c.1528G>C p.A510P | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT tolerated (0.28); PolyPhen benign (0.102); catalogued as rs770679887; called by muse, varscan2
- TAAR5 | c.212T>C p.F71S | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.613); catalogued as COSV57800082; called by muse, mutect2, varscan2
- TASOR2 | c.6059C>T p.S2020L | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs774545747, COSV60166832; called by muse, mutect2, varscan2
- TDRD9 | c.1487G>A p.R496H | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as rs772077271, COSV59158074; called by muse, mutect2, varscan2
- TMEFF1 | c.31C>G p.R11G | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.001); catalogued as COSV100614827; called by muse, mutect2, varscan2
- TRAPPC9 | c.2588C>G p.S863C | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66911634; called by muse, mutect2, varscan2
- TRERF1 | c.1802G>T p.G601V | Missense Mutation (SNP) | VAF 16/104 reads (15%) | SIFT tolerated (0.17); PolyPhen benign (0.005); catalogued as COSV61679321; called by muse, mutect2, varscan2
- TSHZ3 | c.2800C>A p.H934N | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as COSV53685911; called by muse, mutect2, varscan2
- VCX3A | c.540G>A p.M180I | Missense Mutation (SNP) | VAF 26/602 reads (4%) | SIFT tolerated (0.58); PolyPhen benign (0.014); catalogued as rs370418282, COSV101129885; called by muse, mutect2
- WAPL | c.3276G>C p.E1092D | Missense Mutation (SNP) | VAF 11/111 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.259); catalogued as COSV53941173; called by muse, mutect2, varscan2
- WEE2 | c.1229G>A p.R410Q | Missense Mutation (SNP) | VAF 21/77 reads (27%) | SIFT tolerated (0.96); PolyPhen benign (0.015); catalogued as rs1006040516, COSV66879274; called by muse, mutect2, varscan2
- ZNF638 | c.5759A>G p.D1920G | Missense Mutation (SNP) | VAF 10/172 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100039198; called by muse, mutect2
- ZNF704 | c.977G>C p.G326A | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.197); catalogued as COSV100589439, COSV100589660; called by muse, mutect2
- COL3A1 | c.3507_3508del p.G1170* | Frame Shift Del (DEL) | VAF 8/46 reads (17%) | called by pindel, varscan2
- MSH6 | c.3353_3354dup p.E1119Rfs*27 | Frame Shift Ins (INS) | VAF 40/139 reads (29%) | called by mutect2, pindel, varscan2
- MUC16 | c.12216dup p.S4073Lfs*9 | Frame Shift Ins (INS) | VAF 9/65 reads (14%) | called by mutect2, pindel, varscan2
- AFAP1L2 | c.504C>T p.A168= | Silent (SNP) | VAF 19/52 reads (37%) | catalogued as rs185015833, COSV58413311, COSV58419409; called by muse, mutect2, varscan2
- ALDH2 | c.858G>T p.L286= | Silent (SNP) | VAF 8/67 reads (12%) | catalogued as rs554937672, COSV55672572; called by muse, mutect2, varscan2
- BACH2 | c.1785G>A p.S595= | Silent (SNP) | VAF 9/58 reads (16%) | catalogued as rs558363430, COSV57595755; called by muse, mutect2, varscan2
- BDP1 | c.6687A>G p.E2229= | Silent (SNP) | VAF 5/69 reads (7%) | called by muse, mutect2
- CDH22 | c.1254G>A p.A418= | Silent (SNP) | VAF 4/10 reads (40%) | catalogued as rs1253119042, COSV100952922; called by muse, varscan2
- CHST6 | c.159G>A p.S53= | Silent (SNP) | VAF 21/56 reads (38%) | catalogued as rs766289401, COSV60001584; called by muse, mutect2, varscan2
- CLEC4F | c.705G>A p.T235= | Silent (SNP) | VAF 35/106 reads (33%) | catalogued as rs370818847; called by muse, mutect2, varscan2
- COBLL1 | c.1887C>T p.N629= (on ENST00000392717; = p.N591= on NM_014900.5) | Silent (SNP) | VAF 36/270 reads (13%) | catalogued as COSV52078102; called by muse, mutect2, varscan2
- COL16A1 | c.4602C>T p.P1534= | Silent (SNP) | VAF 13/25 reads (52%) | catalogued as rs764706313, COSV54715768; called by muse, mutect2, varscan2
- COL6A3 | c.8373C>T p.N2791= | Silent (SNP) | VAF 14/49 reads (29%) | catalogued as rs770214487, COSV55099897, COSV55115014; called by muse, mutect2, varscan2
- CPA1 | c.1035G>A p.G345= | Silent (SNP) | VAF 7/138 reads (5%) | catalogued as rs1199810756; called by muse, mutect2
- DEF6 | c.1443G>A p.E481= | Silent (SNP) | VAF 6/93 reads (6%) | catalogued as COSV100359402; called by muse, mutect2
- DOCK1 | c.2967C>T p.N989= | Silent (SNP) | VAF 15/32 reads (47%) | catalogued as COSV54764895; called by muse, mutect2, varscan2
- FOXI2 | c.564C>T p.N188= | Silent (SNP) | VAF 17/86 reads (20%) | catalogued as COSV59094573; called by muse, mutect2, varscan2
- GALNTL6 | c.69T>C p.P23= | Silent (SNP) | VAF 28/119 reads (24%) | catalogued as COSV101550705; called by muse, mutect2, varscan2
- IGSF22 | c.1662G>A p.T554= | Silent (SNP) | VAF 9/46 reads (20%) | catalogued as rs1460217601, COSV60039968; called by muse, mutect2, varscan2
- IRGC | c.921G>A p.L307= | Silent (SNP) | VAF 10/19 reads (53%) | catalogued as COSV54986746; called by muse, mutect2, varscan2
- LHX8 | c.234C>T p.C78= | Silent (SNP) | VAF 15/29 reads (52%) | catalogued as rs1326114019, COSV53954836, COSV53957881; called by muse, mutect2, varscan2
- LMTK3 | c.2829G>A p.A943= | Silent (SNP) | VAF 12/30 reads (40%) | catalogued as rs1316394875, COSV54318231; called by muse, mutect2, varscan2
- OPCML | c.336G>A p.P112= | Silent (SNP) | VAF 12/96 reads (13%) | catalogued as rs369569350; called by muse, mutect2, varscan2
- PLXNA3 | c.5451C>T p.H1817= | Silent (SNP) | VAF 31/46 reads (67%) | catalogued as rs374284684, COSV63756120; called by muse, mutect2, varscan2
- PPIL2 | c.999C>A p.G333= | Silent (SNP) | VAF 12/34 reads (35%) | catalogued as COSV58609798; called by muse, mutect2, varscan2
- RBM38 | c.450C>T p.I150= | Silent (SNP) | VAF 51/174 reads (29%) | catalogued as rs569633738, COSV100654889, COSV61135504; called by muse, mutect2, varscan2
- SALL1 | c.3270C>T p.N1090= | Silent (SNP) | VAF 12/41 reads (29%) | catalogued as rs143637930, COSV99171601; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SNORC | c.102G>A p.T34= | Silent (SNP) | VAF 10/26 reads (38%) | catalogued as COSV50966287; called by muse, mutect2
- ST6GALNAC5 | c.483C>T p.N161= | Silent (SNP) | VAF 11/28 reads (39%) | catalogued as rs769598284, COSV59573754; called by muse, mutect2, varscan2
- TCHH | c.3693A>G p.K1231= | Silent (SNP) | VAF 27/80 reads (34%) | catalogued as rs1310726206, COSV100915240; called by muse, mutect2, varscan2
- TUT7 | c.912G>A p.Q304= | Silent (SNP) | VAF 8/124 reads (6%) | catalogued as COSV52895890; called by muse, mutect2
- USH1G | c.1026G>A p.P342= | Silent (SNP) | VAF 5/56 reads (9%) | catalogued as COSV58881643; called by muse, mutect2
- ZNF701 | c.804C>T p.L268= (on ENST00000301093; = p.L202= on NM_018260.3) | Silent (SNP) | VAF 17/68 reads (25%) | catalogued as COSV56527711; called by muse, mutect2, varscan2
